Somatic mutation profile of tumor specimen C3N-01657-02 (aliquot CPT0124170005) from CPTAC case C3N-01657, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G1; Age at diagnosis: 74.6 years (27,232 days).
Specimen C3N-01657-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dfe474f5-6baa-49f6-ac1f-12b8cb2389cc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01657-31 (Blood Derived Normal), aliquot CPT0124200002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7b612d02-8cca-4ec5-8272-de507ef146de

The open-access MAF lists 105 somatic variants for this specimen: 69 protein-altering or splice-affecting, 22 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 55, Silent 22, Intron 10, Frame Shift Del 8, Frame Shift Ins 4, RNA 2, Splice Site 1, Splice Region 1, 3'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACAD10 | c.2213C>T p.A738V | Missense Mutation (SNP) | VAF 18/162 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs1215494551; called by muse, mutect2, varscan2
- C5orf34 | c.160C>T p.R54C | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs751051116, COSV60931222; called by muse, mutect2, varscan2
- C6orf89 | c.344A>G p.Y115C (on ENST00000373685; = p.Y122C on NM_152734.4) | Missense Mutation (SNP) | VAF 38/306 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770263655; called by muse, mutect2, varscan2
- CHD7 | c.8639C>T p.P2880L | Missense Mutation (SNP) | VAF 15/113 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as rs113938624, CM085319, COSV101418705; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CYP4F12 | c.445C>T p.R149W | Missense Mutation (SNP) | VAF 14/214 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.59); catalogued as rs749623963; called by muse, mutect2
- DGCR8 | c.2282C>T p.A761V | Missense Mutation (SNP) | VAF 47/254 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.824); catalogued as rs1203345208; called by muse, mutect2, varscan2
- EPRS1 | c.2374A>G p.K792E | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs748483448; called by muse, mutect2, varscan2
- KCTD21 | c.33dup p.K12Efs*15 | Frame Shift Ins (INS) | VAF 11/74 reads (15%) | catalogued as rs750277188; called by mutect2, pindel, varscan2
- KIT | c.2209G>A p.D737N | Missense Mutation (SNP) | VAF 29/218 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.825); catalogued as rs751005114, COSV55388246, COSV99853506; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MECOM | c.1600A>G p.M534V (on ENST00000468789 / NM_001105078.4; = p.M722V on NM_004991.4) | Missense Mutation (SNP) | VAF 21/119 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs890438183; called by muse, mutect2, varscan2
- NBL1 | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 27/188 reads (14%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.649); catalogued as rs200483320; called by muse, mutect2, varscan2
- PLEKHA6 | c.3134C>G p.T1045S | Missense Mutation (SNP) | VAF 40/342 reads (12%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as COSV55338087; called by muse, mutect2
- POLR2M | c.1096G>A p.D366N | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.407); catalogued as rs1252530115; called by muse, mutect2
- PTPN22 | c.160A>T p.N54Y | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63085338; called by muse, mutect2, varscan2
- SI | c.1151C>A p.T384K | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV52303397; called by muse, mutect2, varscan2
- SPR | c.413T>A p.V138D | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); catalogued as CM102992; called by muse, mutect2, varscan2
- SUN1 | c.1129A>G p.K377E (on ENST00000405266 / NM_001367651.1; = p.K257E on NM_025154.6 and 13 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT tolerated (0.97); PolyPhen benign (0.155); catalogued as rs770728287; called by muse, mutect2, varscan2
- TIAM1 | c.523A>G p.I175V | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.041); catalogued as rs1007341498; called by muse, mutect2
- TVP23A | c.321G>T p.R107S | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.342); catalogued as COSV99296792; called by muse, mutect2
- AASDH | c.2917T>A p.F973I | Missense Mutation (SNP) | VAF 20/152 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.458); called by muse, mutect2, varscan2
- ACSL5 | c.1756G>C p.V586L (on ENST00000354273; = p.V642L on NM_016234.3) | Missense Mutation (SNP) | VAF 22/149 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.244); called by muse, mutect2, varscan2
- ACVR1 | c.710del p.F237Sfs*19 | Frame Shift Del (DEL) | VAF 28/222 reads (13%) | called by mutect2, pindel, varscan2
- BPNT2 | c.749A>C p.K250T | Missense Mutation (SNP) | VAF 51/345 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- BRIP1 | c.2843G>T p.C948F | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.007); called by muse, mutect2
- CHRNB1 | c.314C>A p.A105E | Missense Mutation (SNP) | VAF 69/459 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- CNTNAP5 | c.1070C>G p.T357S | Missense Mutation (SNP) | VAF 23/113 reads (20%) | SIFT tolerated (0.84); PolyPhen probably damaging (0.989); called by muse, varscan2
- CYP27A1 | c.661C>G p.L221V | Missense Mutation (SNP) | VAF 33/286 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.753); called by muse, mutect2, varscan2
- DLEC1 | c.3667-1G>T p.X1223_splice | Splice Site (SNP) | VAF 40/141 reads (28%) | called by mutect2, varscan2
- DYNC1I1 | c.1097T>A p.V366D | Missense Mutation (SNP) | VAF 29/157 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- ELN | c.427+3del | Splice Region (DEL) | VAF 41/413 reads (10%) | called by mutect2, pindel, varscan2
- ERVFRD-1 | c.949T>A p.C317S | Missense Mutation (SNP) | VAF 22/187 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EXT2 | c.1731G>T p.M577I (on ENST00000343631; = p.M610I on NM_000401.3) | Missense Mutation (SNP) | VAF 36/248 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- GALC | c.1069T>C p.Y357H | Missense Mutation (SNP) | VAF 47/250 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- GPR107 | c.1388A>T p.D463V | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- HELZ2 | c.210C>G p.F70L | Missense Mutation (SNP) | VAF 39/268 reads (15%) | SIFT tolerated (0.71); PolyPhen benign (0); called by muse, mutect2, varscan2
- HMCN2 | c.13105A>T p.T4369S | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.57); PolyPhen benign (0.005); called by muse, mutect2
- IFIT2 | c.548A>G p.Y183C | Missense Mutation (SNP) | VAF 27/145 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- INPPL1 | c.587C>T p.A196V | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.867); called by muse, mutect2
- JMY | c.1192A>G p.R398G | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.107); called by muse, mutect2
- KRTAP10-2 | c.473C>T p.S158L | Missense Mutation (SNP) | VAF 109/696 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRRC19 | c.847A>C p.T283P | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- PAMR1 | c.93_97del p.A32Pfs*14 | Frame Shift Del (DEL) | VAF 12/89 reads (13%) | called by mutect2, pindel, varscan2
- PCYOX1 | c.1333T>C p.C445R | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- PDZK1 | c.1433T>G p.L478R | Missense Mutation (SNP) | VAF 37/355 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- PKHD1 | c.4941A>G p.I1647M | Missense Mutation (SNP) | VAF 59/355 reads (17%) | SIFT tolerated (0.72); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- POLR3A | c.1458C>A p.F486L | Missense Mutation (SNP) | VAF 50/339 reads (15%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.712); called by mutect2, varscan2
- POLR3A | c.1451_1455dup p.F486Gfs*22 | Frame Shift Ins (INS) | VAF 44/336 reads (13%) | called by mutect2, varscan2
- POU2F3 | c.839G>T p.R280M | Missense Mutation (SNP) | VAF 26/226 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by mutect2, varscan2
- PRB1 | c.782G>T p.G261V | Missense Mutation (SNP) | VAF 49/408 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PRUNE2 | c.3980A>T p.E1327V | Missense Mutation (SNP) | VAF 35/251 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- RHOT2 | c.1679C>A p.A560D | Missense Mutation (SNP) | VAF 56/391 reads (14%) | SIFT tolerated (0.8); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RTRAF | c.597dup p.A200Sfs*33 | Frame Shift Ins (INS) | VAF 8/69 reads (12%) | called by mutect2, pindel, varscan2
- SH2D4A | c.435C>G p.I145M | Missense Mutation (SNP) | VAF 23/123 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SLC9A3R1 | c.873_874del p.S291Rfs*96 | Frame Shift Del (DEL) | VAF 45/330 reads (14%) | called by mutect2, pindel, varscan2
- TMEM131L | c.3820del p.I1274Lfs*91 | Frame Shift Del (DEL) | VAF 16/137 reads (12%) | called by mutect2, pindel, varscan2
- TMEM236 | c.931dup p.A311Gfs*13 | Frame Shift Ins (INS) | VAF 64/522 reads (12%) | called by mutect2, pindel, varscan2
- TMTC3 | c.859C>A p.L287I | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.481); called by muse, mutect2, varscan2
- TRIM22 | c.590A>C p.E197A | Missense Mutation (SNP) | VAF 35/248 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- TRIM46 | c.461A>T p.E154V | Missense Mutation (SNP) | VAF 24/134 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TTF1 | c.2453del p.K818Rfs*18 | Frame Shift Del (DEL) | VAF 6/38 reads (16%) | called by mutect2, pindel, varscan2
- UBE2Z | c.779A>T p.K260M | Missense Mutation (SNP) | VAF 27/192 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- VPS13C | c.9797A>G p.Q3266R (on ENST00000644861 / NM_020821.3; = p.Q3223R on NM_017684.5) | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF10 | c.1334G>A p.S445N | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.015); called by muse, mutect2
- ZNF132 | c.952del p.Y318Ifs*61 | Frame Shift Del (DEL) | VAF 12/97 reads (12%) | called by mutect2, pindel, varscan2
- ZNF257 | c.147G>C p.K49N | Missense Mutation (SNP) | VAF 20/216 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.071); called by muse, mutect2
- ZNF468 | c.91A>T p.T31S | Missense Mutation (SNP) | VAF 50/302 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF574 | c.610_616del p.E204* | Frame Shift Del (DEL) | VAF 37/292 reads (13%) | called by mutect2, pindel, varscan2
- ZNF704 | c.630_637del p.Q211Hfs*13 | Frame Shift Del (DEL) | VAF 13/95 reads (14%) | called by mutect2, pindel, varscan2
- ZNF865 | c.2303C>A p.S768Y | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT tolerated (0.12); called by muse, mutect2, varscan2
- ABL2 | c.1881A>G p.Q627= (on ENST00000502732 / NM_007314.4; = p.Q612= on NM_005158.5) | Silent (SNP) | VAF 32/154 reads (21%) | catalogued as rs982075065; called by muse, mutect2, varscan2
- AC011462.1 | c.414G>A p.K138= | Silent (SNP) | VAF 40/341 reads (12%) | called by muse, mutect2, varscan2
- ARL8A | c.519C>A p.T173= | Silent (SNP) | VAF 22/177 reads (12%) | called by muse, mutect2, varscan2
- CHPF | c.1431C>A p.G477= | Silent (SNP) | VAF 31/206 reads (15%) | called by muse, mutect2, varscan2
- CPXM1 | c.483A>C p.G161= | Silent (SNP) | VAF 21/154 reads (14%) | called by muse, mutect2, varscan2
- DPP6 | c.636A>G p.Q212= (on ENST00000377770 / NM_001364500.2; = p.Q150= on NM_001936.5) | Silent (SNP) | VAF 7/62 reads (11%) | called by muse, mutect2
- DSG1 | c.921T>A p.I307= | Silent (SNP) | VAF 5/43 reads (12%) | called by muse, mutect2, varscan2
- FAM102B | c.567A>C p.A189= | Silent (SNP) | VAF 18/103 reads (17%) | called by muse, mutect2, varscan2
- FUOM | c.75G>C p.G25= | Silent (SNP) | VAF 27/187 reads (14%) | called by muse, mutect2, varscan2
- HSPA4L | c.435T>A p.P145= | Silent (SNP) | VAF 18/124 reads (15%) | called by muse, mutect2, varscan2
- HYAL4 | c.1182G>A p.A394= | Silent (SNP) | VAF 41/279 reads (15%) | catalogued as rs138391454; called by muse, mutect2, varscan2
- IFRD1 | c.228T>A p.T76= | Silent (SNP) | VAF 25/159 reads (16%) | called by muse, mutect2, varscan2
- MARS2 | c.1776G>A p.R592= | Silent (SNP) | VAF 6/88 reads (7%) | catalogued as rs1213048124; called by muse, mutect2
- MCM3AP | c.4308C>T p.L1436= | Silent (SNP) | VAF 12/70 reads (17%) | called by muse, mutect2
- OTOA | c.417C>T p.I139= | Silent (SNP) | VAF 42/308 reads (14%) | catalogued as COSV53758256; called by muse, mutect2, varscan2
- PCDHA5 | c.1722C>T p.G574= | Silent (SNP) | VAF 105/416 reads (25%) | catalogued as COSV65350914; called by muse, mutect2, varscan2
- PCDHGB6 | c.1140A>C p.G380= | Silent (SNP) | VAF 28/103 reads (27%) | called by muse, mutect2, varscan2
- PCYOX1L | c.1131C>A p.V377= | Silent (SNP) | VAF 84/357 reads (24%) | called by muse, mutect2, varscan2
- PDCD11 | c.5484C>A p.P1828= | Silent (SNP) | VAF 26/129 reads (20%) | called by muse, varscan2
- PEBP1 | c.168T>C p.D56= | Silent (SNP) | VAF 36/259 reads (14%) | catalogued as rs1217134646; called by muse, mutect2, varscan2
- RTEL1 | c.3222G>C p.A1074= | Silent (SNP) | VAF 45/276 reads (16%) | called by muse, mutect2, varscan2
- TBX21 | c.117G>A p.E39= | Silent (SNP) | VAF 43/277 reads (16%) | called by muse, mutect2, varscan2
- AMFR | c.*568A>T | 3'UTR (SNP) | VAF 27/196 reads (14%) | called by muse, mutect2, varscan2
- COX4I1 | c.374-29C>A | Intron (SNP) | VAF 46/251 reads (18%) | catalogued as COSV99495575; called by muse, mutect2, varscan2
- CRACR2B | c.694-103A>T | Intron (SNP) | VAF 33/160 reads (21%) | called by muse, mutect2, varscan2
- DYSF | c.88+12842T>G | Intron (SNP) | VAF 9/94 reads (10%) | called by muse, mutect2
- DYSF | c.88+12843C>A | Intron (SNP) | VAF 9/94 reads (10%) | called by muse, mutect2
- FAM104B | c.20+187G>A | Intron (SNP) | VAF 46/161 reads (29%) | called by muse, varscan2
- LINC00967 | n.864G>C | RNA (SNP) | VAF 3/28 reads (11%) | called by muse, mutect2
- LINC02206 | n.413A>T | RNA (SNP) | VAF 15/102 reads (15%) | called by muse, mutect2, varscan2
- MAP2K6 | c.484-15G>A | Intron (SNP) | VAF 4/24 reads (17%) | called by muse, mutect2
- PRDM11 | chr11:45226245 del A | 3'Flank (DEL) | VAF 16/136 reads (12%) | called by mutect2, pindel, varscan2
- SEC31B | c.1411-524A>C | Intron (SNP) | VAF 44/274 reads (16%) | called by muse, mutect2, varscan2
- SLC45A4 | c.-400-1999G>T | Intron (SNP) | VAF 12/115 reads (10%) | called by muse, mutect2, varscan2
- STXBP2 | c.246+31G>A | Intron (SNP) | VAF 89/526 reads (17%) | catalogued as rs369364806; called by muse, mutect2, varscan2
- TIA1 | c.311-596dup | Intron (INS) | VAF 8/77 reads (10%) | called by mutect2, pindel, varscan2
